Gene-level copy-number profile of tumor specimen TCGA-37-5819-01A from TCGA case TCGA-37-5819, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 65.0 years (23,726 days).
Specimen TCGA-37-5819-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.a1479192-761c-49c4-9f5a-df3521fa73f4.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-37-5819-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/7682837b-0510-47a3-b2f1-2592c467ac26

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 96; copy number 1: 2,394; copy number 2: 21,686; copy number 3: 16,769; copy number 4: 11,962; copy number 5: 5,079; copy number 6: 1,716; copy number 7: 12; copy number 9: 57; copy number 10: 38; copy number 11: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-37-5819-01A-01D-1631-01): tumor purity 0.71, ploidy 2.94, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 96 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:10,532,145–12,823,060, 18 genes (within-gene range 0–2): AL135790.2, PTPRD-AS2, AL135790.1, AL161788.1, IMP3P1, AL162413.1, AKAP8P1, AL451129.1, AL355672.1, AL592227.1, AL353595.1, AL589678.1, JKAMPP1, RNU2-47P, TYRP1, LURAP1L-AS1, RN7SL849P, LURAP1L.
- chr9:13,274,510–14,722,733, 20 genes: AL162386.2, AL162386.1, AL583785.1, LINC01235, AL158157.1, LINC00583, PES1P2, AL360089.1, RPL3P11, ATP5PDP3, NFIB, AL441963.1, AL136366.1, AL137017.1, AL159169.1, AL159169.3, AL159169.2, CDCA4P1, ZDHHC21, CER1.
- chr9:14,779,930–14,784,117, 1 gene: AL512643.2.
- chr9:21,802,636–23,438,700, 20 genes (within-gene range 0–2): MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1.
- chr10:44,712–931,705, 15 genes (within-gene range 0–4): AL713922.1, TUBB8, IL9RP2, ZMYND11, AL713922.2, RNA5SP297, DIP2C, RNA5SP298, RN7SL754P, AL669841.1, AL358216.1, MIR5699, PRR26, AL157709.1, LARP4B.
- chr10:13,870,797–13,871,175, 1 gene: NUTF2P5.
- chr22:50,541,108–50,801,309, 21 genes: U62317.3, KLHDC7B-DT, KLHDC7B, SYCE3, CPT1B, CHKB-CPT1B, CHKB, CHKB-DT, U62317.2, MAPK8IP2, ARSA, Y_RNA, AC000050.2, SHANK3, RNU6-409P, AC000036.1, ACR, AC002056.2, AC002056.1, RPL23AP82, RABL2B.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 6,903 genes in 41 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:3,069,168–3,438,621, 1 gene, copy number 6 (within-gene range 4–6): PRDM16.
- chr1:3,205,988–3,736,201, 14 genes, copy number 6 (within-gene range 3–6): AL512383.1, AL590438.1, AL354743.2, AL354743.1, ARHGEF16, AL512413.1, MEGF6, MIR551A, AL513320.1, TPRG1L, WRAP73, TP73, TP73-AS3, TP73-AS2.
- chr1:143,343,180–162,370,475, 854 genes, copy number 5–6 (within-gene range 3–6) (broad region; genes not listed).
- chr1:162,316,852–200,483,604, 623 genes, copy number 5–6 (broad region; genes not listed).
- chr2:183,253,652–183,495,501, 2 genes, copy number 5: AC021851.2, LIN28AP1.
- chr3:162,486,541–167,407,874, 33 genes, copy number 5 (within-gene range 4–5): TOMM22P6, AC128716.1, AC128685.1, LINC01192, RPS6P4, AC079910.1, RNU7-82P, AC084017.1, MIR1263, LINC01323, LINC01324, SI, Y_RNA, LINC02023, SLITRK3, LINC01322, BCHE, MTND4P17, MTND4LP10, MTND3P7, MTCO3P38, MCUR1P2, AC104629.1, LINC01326, AC072046.2, RN7SKP298, PSAT1P4, AC072046.1, CBX1P5, AC069439.2, AC069439.1, PPIAP74, ZBBX.
- chr3:175,938,929–176,114,537, 5 genes, copy number 7: AC104640.1, ACTG1P23, EI24P1, AC104640.2, AC117434.1.
- chr3:177,019,340–198,222,513, 476 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr5:12,297,399–13,190,677, 7 genes, copy number 5: RNU6-679P, AC106771.1, LINC01194, AC106794.2, AC106794.1, LINC02220, AC016553.1.
- chr5:17,684,584–31,066,132, 117 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr5:139,221,758–140,043,299, 38 genes, copy number 10: RNU6-572P, MATR3, SNHG4, SNORA74D, SNORA74A, MATR3, RNA5SP195, RN7SKP64, PAIP2, AC135457.1, SLC23A1, MZB1, PROB1, SPATA24, DNAJC18, AC142391.1, RNU5B-4P, ECSCR, SMIM33, STING1, AC138517.1, NCOA4P4, AC010378.1, UBE2D2, Y_RNA, H3P25, AC113361.1, CXXC5, CXXC5-AS1, AC008667.1, RNU6-236P, PSD2-AS1, AC008667.3, AC008667.4, PSD2, NRG2, AC008667.2, Y_RNA.
- chr5:143,277,931–146,407,359, 41 genes, copy number 6: NR3C1, RPL7P21, AC091925.2, AC091925.1, AC016598.1, AC016598.2, RNU7-156P, AC008696.2, MIR5197, AC008696.1, HMHB1, RN7SL87P, YIPF5, KCTD16, AC008652.1, AC109441.1, CKS1BP5, AC008716.1, RN7SKP246, AC132803.1, NAMPTP2, ASS1P10, AC137770.1, AC008700.1, PRELID2, AC011411.1, GRXCR2, SH3RF2, AC005351.1, PLAC8L1, AC091887.1, LARS1, RPL35AP16, RPL35AP17, AC091959.1, RBM27, RNU7-180P, AC011396.2, POU4F3, AC011396.3, AC011396.1.
- chr6:97,283,303–98,780,505, 6 genes, copy number 7 (within-gene range 2–7): AL589740.1, AL080316.1, MIR2113, EIF4EBP2P3, AL590727.1, AL589826.1.
- chr7:25,358,235–26,497,595, 17 genes, copy number 6 (within-gene range 4–6): AC005100.1, AC005100.2, AC091705.1, AC005165.1, AC005165.2, AC005165.3, AC018706.1, AC010719.1, MIR148A, NFE2L3, HNRNPA2B1, CBX3, AC010677.2, AC010677.1, SNX10, AC004540.2, AC004540.1.
- chr7:40,964,667–41,133,507, 2 genes, copy number 5: LINC01450, LINC01449.
- chr8:43,018,424–48,194,627, 72 genes, copy number 5 (broad region; genes not listed).
- chr8:52,534,037–63,014,681, 157 genes, copy number 6–11 (within-gene range 4–11) (broad region; genes not listed).
- chr8:116,642,130–145,066,685, 501 genes, copy number 5 (broad region; genes not listed).
- chr9:36,572,862–37,465,450, 23 genes, copy number 6: MELK, AL442063.1, AL450267.2, MIR4475, PAX5, AL450267.1, MIR4540, MIR4476, AL161781.2, AL161781.1, LINC01400, AL512604.3, EBLN3P, AL512604.2, ZCCHC7, Y_RNA, AL512604.1, Y_RNA, RNU6-677P, LINC01627, GRHPR, CHCHD4P3, ZBTB5.
- chr10:27,110,111–29,736,959, 57 genes, copy number 9 (within-gene range 4–9): YME1L1, MASTL, ACBD5, RNU2-24P, RNU7-12P, AL160291.1, LRRC37A6P, ARMC4P1, AL355493.6, RNU6-666P, AL355493.1, RNU6-452P, LINC02673, FAM210CP, TRIAP1P1, PTCHD3, RAB18, LINC02680, MKX, MKX-AS1, ARMC4, RN7SKP132, RPL36AP55, AL390866.1, MRPS21P5, MPP7, AL355501.1, MIR8086, MPP7-DT, ZNF101P1, U3, LINC02652, RPSAP10, RN7SKP39, WAC-AS1, WAC, RNU4ATAC6P, TPRKBP1, RNU6-1067P, BAMBI, LINC01517, AL355376.1, RNU6-270P, LINC00837, AL355376.2, RNA5SP308, RPL21P93, LYZL1, AL158167.1, SVIL-AS1, PTCHD3P1, SVIL, MIR604, SNORD115, MIR938, CKS1BP2, RNU6-908P.
- chr10:133,144,612–133,761,125, 52 genes, copy number 5: RPL5P28, KNDC1, UTF1, VENTX, MIR202HG, MIR202, AL592071.1, ADAM8, TUBGCP2, AL360181.2, ZNF511, ZNF511-PRAP1, CALY, BANF1P2, AL360181.1, PRAP1, FUOM, ECHS1, MIR3944, AL360181.4, PAOX, AL360181.3, MTG1, SPRN, OR6L2P, SCART1, OR7M1P, CYP2E1, AL161645.1, AL161645.2, SYCE1, AL731769.2, OR6L1P, AL731769.1, FRG2B, RARRES2P2, AGGF1P2, CLUHP5, DUX4L28, DUX4L25, DUX4L24, DUX4L23, DUX4L22, DUX4L21, DUX4L20, DUX4L29, DUX4L10, DUX4L11, DUX4L12, DUX4L13, DUX4L14, DUX4L15.
- chr11:91,115,961–93,241,168, 29 genes, copy number 5 (within-gene range 4–5): OSBPL9P3, LINC02748, AP003485.2, AP003485.1, AP002791.1, LINC02756, TUBB4BP4, AP002799.1, RPL7AP57, NDUFB11P1, FAT3, PGAM1P9, AP000722.1, RPS3AP42, AP003718.1, LINC02746, AP003171.2, SNRPGP16, AP003171.1, MTNR1B, RPL26P31, AP002371.1, AP003072.4, SLC36A4, AP003072.2, AP003072.5, AP003072.3, AP003072.1, AP003969.1.
- chr12:66,767–911,452, 22 genes, copy number 5 (within-gene range 3–5): IQSEC3, AC026369.3, AC026369.1, AC026369.2, AC007406.3, SLC6A12, AC007406.1, SLC6A12-AS1, SLC6A13, AC007406.2, AC007406.4, KDM5A, CCDC77, B4GALNT3, NINJ2, AC006205.2, RNU7-103P, AC006205.1, NINJ2-AS1, LINC02455, WNK1, RNU4ATAC16P.
- chr12:4,247,981–6,160,719, 41 genes, copy number 5: CCND2-AS1, CCND2, AC008012.1, TIGAR, AC006122.1, FGF23, FGF6, C12orf4, RAD51AP1, DYRK4, AC005832.2, AC005832.4, AKAP3, AC005832.3, AC005832.1, NDUFA9, AC005833.1, GAU1, GALNT8, AC005833.2, KCNA6, AC006063.1, AC006063.3, AC006063.4, AC005906.2, KCNA1, AC006063.2, AC005906.1, KCNA5, AC005906.3, LINC02443, AC006206.2, AC006206.1, AC007848.2, AC007848.1, NTF3, ANO2, AC137627.1, VWF, RN7SL69P, AC005845.1.
- chr12:7,470,811–11,590,369, 212 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr12:18,080,869–18,320,107, 1 gene, copy number 5 (within-gene range 3–5): RERGL.
- chr12:18,358,443–18,358,967, 1 gene, copy number 5: NDFIP1P1.
- chr12:33,374,238–33,718,217, 6 genes, copy number 6: SYT10, AC023158.1, AC023158.2, AC016956.1, RNU6-400P, AC024153.1.
- chr12:103,503,381–133,214,832, 787 genes, copy number 5–6 (broad region; genes not listed).
- chr14:78,170,373–87,332,390, 73 genes, copy number 5 (broad region; genes not listed).
- chr16:84,974,175–85,848,138, 29 genes, copy number 5: ZDHHC7, KIAA0513, CIBAR2, LINC02139, AC026469.1, GSE1, AC092275.1, COX6CP16, LINC00311, MIR5093, AC092377.1, AC133540.1, AC092127.2, AC092127.1, RN7SL381P, GINS2, C16orf74, AC018695.6, AC018695.9, MIR1910, AC018695.2, EMC8, RNU1-103P, AC018695.4, AC018695.3, COX4I1, AC018695.5, AC018695.1, AC018695.8.
- chr17:54,477,796–57,121,346, 44 genes, copy number 5: ISCA1P3, AC015943.1, AC005951.1, ARL2BPP8, RN7SKP14, TOM1L1, COX11, AC007485.2, AC007485.1, STXBP4, HLF, AC007638.2, AC007638.1, MMD, SMIM36, AC105021.1, GARS1P1, RNU6-1249P, TMEM100, PCTP, AC090618.1, ANKFN1, AC006600.1, AC006600.2, RPL39P33, NOG, C17orf67, AC106858.1, DGKE, TRIM25, RNU6-1158P, AC015912.2, AC015912.1, MIR3614, AC015912.3, COIL, AC004584.1, AC004584.2, SCPEP1, AC004584.3, RNF126P1, AC007114.1, AKAP1, AC007114.2.
- chr17:58,218,548–58,268,518, 1 gene, copy number 5 (within-gene range 3–5): LPO.
- chr17:58,241,164–82,490,537, 804 genes, copy number 5–6 (broad region; genes not listed).
- chr19:31,797,666–43,781,257, 570 genes, copy number 6 (within-gene range 3–6) (broad region; genes not listed).
- chr19:43,794,309–43,795,658, 1 gene, copy number 6: AC115522.1.
- chr19:44,382,298–58,605,223, 1,000 genes, copy number 5 (broad region; genes not listed).
- chr20:3,777,504–13,368,703, 154 genes, copy number 5–6 (broad region; genes not listed).
- chr20:13,392,677–13,393,674, 1 gene, copy number 5: GAPDHP2.
- chr20:62,302,093–62,685,785, 28 genes, copy number 6: ADRM1, AL354836.1, LAMA5, MIR4758, LAMA5-AS1, AL121832.2, RPS21, CABLES2, AL121832.3, RBBP8NL, AL121832.1, GATA5, AL499627.2, AL499627.1, MIR1-1HG-AS1, MIR1-1HG, MIR1-1, MIR133A2, RPL7P3, BX640514.1, BX640514.2, AL450469.2, AL450469.1, AL357033.1, SLCO4A1, AL357033.4, AL357033.3, SLCO4A1-AS1.

Autosomal genes at a single copy (total copy number 1): 2,010. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
